TCGA case TCGA-AO-A12B — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f6ed684f-ee7a-496c-80d5-6eacd494d16a

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 63.4 years (23,150 days); Year of diagnosis: 2004; Method of diagnosis: Core Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0 (i-); AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Right Upper Inner / Breast, Right Lower Inner / Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 2; Micrometastasis present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Fluorouracil; Treatment intent type: Adjuvant; Days to treatment start: 45 days; Days to treatment end: 118 days; Number of cycles: 4; Treatment dose: 3,924 mg; Prescribed dose: 600; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Methotrexate; Treatment intent type: Adjuvant; Days to treatment start: 45 days; Days to treatment end: 118 days; Number of cycles: 4; Treatment dose: 262 mg; Prescribed dose: 40; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Anastrozole; Treatment intent type: Adjuvant; Days to treatment start: 140 days; Days to treatment end: 1,980 days (5.4 years); Prescribed dose: 1; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 2,359 days (6.5 years); Disease response: Tumor Free.
- Days to follow up: 2,989 days (8.2 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 2,622.

Molecular and laboratory tests
- ERBB2 (IHC): Negative; Staining intensity value: 0; Test value range: <10%.
- ESR1 (IHC): Positive; Staining intensity value: 4+; Test value range: 90-99%.
- PGR (IHC): Positive; Staining intensity value: 4+; Test value range: 90-99%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AO-A12B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 570 mg.
  Slide TCGA-AO-A12B-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-AO-A12B-01A-01-BSA: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-AO-A12B-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AO-A12B-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Axillary staging method: Sentinel node biopsy alone; Surgical procedure first: Simple Mastectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Micromet detection by IHC: Yes; Er IHC score: 4+; Her2 IHC score: 0; Method initial path diagnosis: Core needle biopsy; Her2 IHC percent positive: <10%; Her2 positivity method text: 3+ Positive; Prospective collection: No; Retrospective collection: Yes.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right Upper Inner Quadrant; Anatomic organ subdivision: Right Lower Inner Quadrant; Anatomic organ subdivision: Right.
- Follow-up form 2: New tumor event diagnosis indicator: No.
- Follow-up form 3: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Regimen number: 2; Pharmaceutical therapy drug name: Arimidex.
- Drug treatment 3, Route of administrations: Route of administration: PO.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,989 days; disease-specific survival: no event (censored), 2,989 days; disease-free interval: no event (censored), 2,989 days; progression-free interval: no event (censored), 2,989 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-AO-A12B-01): tumor purity 0.78, ploidy 3.5, whole-genome doublings 1 (call status: maf_call).
